Somatic mutation profile of tumor specimen C3N-04126-01 (aliquot CPT0238040008) from CPTAC case C3N-04126, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 43.0 years (15,708 days).
Specimen C3N-04126-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) da92097f-8fa7-41fd-adcc-e8a3e1e6143b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-04126-31 (Blood Derived Normal), aliquot CPT0238100002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5fae4f1a-8ce3-4433-b155-f00911f56b70

The open-access MAF lists 43 somatic variants for this specimen: 32 protein-altering or splice-affecting, 7 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 7, Intron 3, Nonsense Mutation 2, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL3A1 | c.2222G>A p.G741D | Missense Mutation (SNP) | VAF 65/569 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs553203474, CM1412597; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 120/998 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 84/483 reads (17%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.4078C>T p.R1360W | Missense Mutation (SNP) | VAF 17/170 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs768328938, COSV52204487; called by muse, mutect2, varscan2
- ANKZF1 | c.467G>A p.R156Q | Missense Mutation (SNP) | VAF 57/530 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs373389031, COSV99850356; called by muse, mutect2, varscan2
- AP1G1 | c.1564A>G p.T522A | Missense Mutation (SNP) | VAF 27/389 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs555677572; called by muse, mutect2
- C1orf43 | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 35/323 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.037); catalogued as COSV99672087; called by muse, mutect2, varscan2
- CASP12 | c.164C>G p.A55G | Missense Mutation (SNP) | VAF 20/223 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.121); catalogued as COSV65259259; called by muse, mutect2
- DYNC2H1 | c.3928C>T p.Q1310* | Nonsense Mutation (SNP) | VAF 60/538 reads (11%) | catalogued as COSV100518488; called by muse, mutect2, varscan2
- IHH | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 35/266 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777059543; called by muse, mutect2, varscan2
- KRT24 | c.1020C>T p.S340= | Splice Region (SNP) | VAF 46/291 reads (16%) | catalogued as rs750253983; called by muse, mutect2, varscan2
- LGI1 | c.269C>T p.T90M | Missense Mutation (SNP) | VAF 52/560 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.021); catalogued as rs796052692; ClinVar: uncertain significance; called by muse, mutect2
- RNASE3 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 109/835 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs115812876, COSV58959154; called by muse, mutect2, varscan2
- SLC7A4 | c.1237C>T p.R413C | Missense Mutation (SNP) | VAF 51/440 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371765676; called by muse, mutect2, varscan2
- SNX7 | c.887C>T p.S296L | Missense Mutation (SNP) | VAF 49/327 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.84); catalogued as COSV60271780; called by muse, mutect2, varscan2
- TP53 | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 57/377 reads (15%) | catalogued as CM107390, COSV52689258; called by muse, mutect2, varscan2
- ZXDC | c.2482G>A p.V828I | Missense Mutation (SNP) | VAF 112/731 reads (15%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs1027630984; called by muse, mutect2, varscan2
- ABCA12 | c.5209T>C p.F1737L (on ENST00000272895 / NM_173076.3; = p.F1419L on NM_015657.3) | Missense Mutation (SNP) | VAF 66/370 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.729); called by muse, mutect2, varscan2
- CPEB2 | c.458C>G p.S153C | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious, low confidence (0); called by muse, mutect2
- CYB5R3 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 61/568 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FAT3 | c.4592A>T p.K1531M | Missense Mutation (SNP) | VAF 24/192 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); called by muse, mutect2
- GAK | c.128G>T p.R43L | Missense Mutation (SNP) | VAF 137/892 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- GBE1 | c.1723C>T p.L575F | Missense Mutation (SNP) | VAF 57/298 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HERC2 | c.205A>T p.S69C | Missense Mutation (SNP) | VAF 82/332 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.174); called by muse, mutect2
- MED13 | c.2958G>A p.M986I | Missense Mutation (SNP) | VAF 47/303 reads (16%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- NR1D2 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- PSEN2 | c.1297C>G p.L433V | Missense Mutation (SNP) | VAF 75/530 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- SLC52A2 | c.987G>C p.M329I | Missense Mutation (SNP) | VAF 36/197 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.246); called by muse, mutect2, varscan2
- TCIRG1 | c.2342C>G p.A781G | Missense Mutation (SNP) | VAF 109/942 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRDMT1 | c.683T>G p.I228S | Missense Mutation (SNP) | VAF 46/315 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- TRIB2 | c.584G>T p.S195I | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); called by muse, mutect2
- TUT4 | c.3202G>A p.E1068K | Missense Mutation (SNP) | VAF 22/260 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- COL20A1 | c.555C>T p.D185= | Silent (SNP) | VAF 44/315 reads (14%) | catalogued as rs767672689; called by muse, mutect2, varscan2
- FAT2 | c.9741C>T p.G3247= | Silent (SNP) | VAF 106/716 reads (15%) | catalogued as rs772008822; called by muse, mutect2, varscan2
- FLNC | c.1848C>T p.I616= | Silent (SNP) | VAF 34/195 reads (17%) | catalogued as rs770173704, COSV57966871; called by muse, mutect2, varscan2
- NDNF | c.1500A>G p.Q500= | Silent (SNP) | VAF 67/530 reads (13%) | called by muse, mutect2, varscan2
- OR6K2 | c.45C>T p.S15= | Silent (SNP) | VAF 22/153 reads (14%) | catalogued as rs929760142, COSV100656709; called by muse, mutect2
- R3HDM4 | c.783C>T p.S261= | Silent (SNP) | VAF 28/220 reads (13%) | catalogued as rs375137933; called by muse, mutect2, varscan2
- VPS13D | c.8139C>T p.I2713= | Silent (SNP) | VAF 76/650 reads (12%) | catalogued as rs752121874; called by muse, mutect2, varscan2
- AGPAT4 | c.843+2327C>T | Intron (SNP) | VAF 45/355 reads (13%) | catalogued as rs938734659; called by muse, mutect2, varscan2
- CDC42BPA | c.2904+1109G>T | Intron (SNP) | VAF 8/90 reads (9%) | called by muse, mutect2
- FAAP20 | c.470+35C>A | Intron (SNP) | VAF 24/175 reads (14%) | called by muse, mutect2, varscan2
- LINC00529 | n.219C>T | RNA (SNP) | VAF 20/118 reads (17%) | called by muse, mutect2, varscan2
